Somatic mutation profile of tumor specimen TCGA-OR-A5KT-01A (aliquot TCGA-OR-A5KT-01A-11D-A29I-10) from TCGA case TCGA-OR-A5KT, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 44.4 years (16,217 days).
Specimen TCGA-OR-A5KT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36efc5c3-6958-4a16-9caf-6191f319a916.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5KT-10A (Blood Derived Normal), aliquot TCGA-OR-A5KT-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce848c76-3754-436f-a8b7-06aaf923ed6c

The open-access MAF lists 26 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 5, Frame Shift Del 3, Frame Shift Ins 2, Nonsense Mutation 2, Splice Site 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V0A1 | c.2341G>A p.A781T (on ENST00000343619 / NM_001378531.1; = p.A775T on NM_005177.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.383); catalogued as COSV99230239; called by muse, mutect2, varscan2
- CEP104 | c.2648C>T p.P883L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1197412379, COSV65517422; called by muse, mutect2, varscan2
- CEP128 | c.2726A>G p.K909R | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.047); catalogued as COSV55382828; called by muse, mutect2, varscan2
- CLDN5 | c.352G>C p.A118P (on ENST00000618236 / NM_001363066.2; = p.A203P on NM_003277.4) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.903); catalogued as rs1314602205, COSV54248882; called by muse, mutect2
- MYO9B | c.6178dup p.R2060Pfs*140 | Frame Shift Ins (INS) | VAF 5/22 reads (23%) | catalogued as rs1388909247; called by pindel, varscan2
- ALPK1 | c.2280del p.R760Sfs*41 | Frame Shift Del (DEL) | VAF 14/53 reads (26%) | called by mutect2, pindel, varscan2
- ATP11C | c.517A>G p.T173A | Missense Mutation (SNP) | VAF 10/352 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATRX | c.1426C>T p.Q476* | Nonsense Mutation (SNP) | VAF 18/62 reads (29%) | called by muse, mutect2, varscan2
- DOCK2 | c.4247A>T p.D1416V | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.069); called by muse, mutect2
- GRM5 | c.921G>C p.W307C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GTF3C2 | c.1044C>G p.Y348* | Nonsense Mutation (SNP) | VAF 52/162 reads (32%) | called by muse, mutect2, varscan2
- IGLC2 | c.143del p.V49Sfs*24 | Frame Shift Del (DEL) | VAF 94/892 reads (11%) | called by mutect2, varscan2
- IGLC3 | c.143del p.V49Sfs*24 | Frame Shift Del (DEL) | VAF 106/566 reads (19%) | called by mutect2, varscan2
- IMPG1 | c.2248C>G p.P750A | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- MACF1 | c.17246dup p.L5750Ifs*13 (on ENST00000372915; = p.L3792Ifs*13 on NM_012090.5) | Frame Shift Ins (INS) | VAF 73/266 reads (27%) | called by mutect2, pindel, varscan2
- RFX1 | c.897G>C p.E299D | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SKIV2L | c.2530G>A p.V844M | Missense Mutation (SNP) | VAF 11/229 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- SLC6A1 | c.1324-1G>T p.X442_splice | Splice Site (SNP) | VAF 26/61 reads (43%) | called by muse, mutect2, varscan2
- TTC26 | c.1505G>C p.G502A | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANKIB1 | c.1041G>A p.V347= | Silent (SNP) | VAF 51/164 reads (31%) | called by muse, mutect2, varscan2
- EEF1A1 | c.849C>T p.V283= | Silent (SNP) | VAF 18/602 reads (3%) | called by muse, mutect2
- MSR1 | c.1314C>G p.A438= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as COSV100027143, COSV50537617; called by muse, mutect2, varscan2
- PRICKLE2 | c.1261C>T p.L421= (on ENST00000295902; = p.L365= on NM_198859.4) | Silent (SNP) | VAF 27/99 reads (27%) | catalogued as rs539536335; called by muse, mutect2, varscan2
- SAMD4B | c.1686C>G p.G562= | Silent (SNP) | VAF 4/70 reads (6%) | called by muse, mutect2
- DST | c.4297-3647T>A | Intron (SNP) | VAF 10/136 reads (7%) | called by muse, mutect2
- MIR512-2 | n.44G>T | RNA (SNP) | VAF 59/315 reads (19%) | called by muse, mutect2, varscan2
